Gene-level copy-number profile of tumor specimen TCGA-AA-A02K-01A from TCGA case TCGA-AA-A02K, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.7 years (18,506 days).
Specimen TCGA-AA-A02K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.500069b9-de7c-453c-8da2-7cf1794487bc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A02K-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 366 have no estimate.
https://portal.gdc.cancer.gov/files/9067c9a3-ec3b-41db-a0a6-7aa75d7d7887

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,067; copy number 1: 14,466; copy number 2: 35,752; copy number 3: 6,776; copy number 4: 1,213; copy number 5: 641; copy number 6: 183; copy number 7: 98; copy number 8: 21; copy number 9: 15; copy number 11: 12; copy number 13: 11; copy number 18: 1; copy number 31: 1.

Homozygous deletions (total copy number 0; autosomes only): 492 genes in 68 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,412,027–4,424,689, 1 gene: LINC01777.
- chr1:29,904,865–30,421,108, 6 genes: AL645944.1, LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1.
- chr1:36,630,335–37,034,515, 5 genes (within-gene range 0–2): FTLP18, AL596257.1, AC117945.2, AC117945.1, GRIK3.
- chr2:120,735,623–120,992,653, 2 genes (within-gene range 0–1): GLI2, AC017033.1.
- chr4:6,909,242–7,742,836, 14 genes (within-gene range 0–2): TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36, SORCS2, MIR4798, PSAPL1, MIR4274.
- chr5:141,822,076–141,879,246, 3 genes (within-gene range 0–8): AC005753.3, AC005753.1, PCDH1.
- chr5:173,689,459–173,809,039, 4 genes (within-gene range 0–2): LINC01942, LINC01484, AC008674.1, LINC01485.
- chr7:30,852,273–30,993,254, 3 genes: AC004691.2, AQP1, GHRHR.
- chr8:8,783,354–10,554,166, 41 genes (within-gene range 0–1): MFHAS1, RNU6-682P, AC087763.1, RPL10P19, SNORA70, ERI1, MIR4660, RNU7-55P, Metazoa_SRP, PPP1R3B, AC022784.5, AC022784.1, AC022784.6, AC022784.2, AC022784.4, AC022784.3, RNU6-1151P, AC021736.1, AC021242.2, RNU6-526P, AC021242.1, AC021242.3, TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55.
- chr8:23,678,697–36,936,125, 226 genes (within-gene range 0–4) (broad region; genes not listed).
- chr8:39,902,275–40,127,468, 8 genes (within-gene range 0–1): IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866.
- chr8:40,530,590–41,032,998, 3 genes (within-gene range 0–1): ZMAT4, AC048387.1, RNU6-356P.
- chr8:142,176,339–142,209,003, 2 genes: MIR4472-1, LINC00051.
- chr9:134,527,182–134,844,843, 5 genes (within-gene range 0–1): AL669970.3, AL669970.2, COL5A1, COL5A1-AS1, AL645768.1.
- chr9:135,075,422–135,237,597, 2 genes (within-gene range 0–1): OLFM1, AL390778.1.
- chr10:71,212,570–71,381,423, 4 genes: UNC5B, UNC5B-AS1, SLC29A3, AL359183.1.
- chr10:78,696,062–79,067,895, 3 genes (within-gene range 0–1): AC016820.1, ZMIZ1-AS1, AL356753.1.
- chr10:96,304,409–96,359,365, 2 genes (within-gene range 0–2): DNTT, OPALIN.
- chr11:11,239,759–11,243,715, 2 genes: MTND5P21, KC877392.1.
- chr11:44,726,465–44,951,306, 2 genes (within-gene range 0–1): TSPAN18, TP53I11.
- chr11:45,371,397–45,583,474, 7 genes (within-gene range 0–1): LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1.
- chr11:117,427,772–117,817,525, 3 genes (within-gene range 0–2): DSCAML1, AP000711.1, AP001554.1.
- chr11:119,821,304–120,013,620, 6 genes (within-gene range 0–1): AP001994.1, AP001994.2, AP001994.3, AP001360.3, LINC02744, AP001360.1.
- chr13:18,905,419–19,062,718, 7 genes (within-gene range 0–4): LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1.
- chr15:73,870,949–73,952,137, 4 genes: AC018943.1, TBC1D21, LOXL1-AS1, LOXL1.
- chr16:86,035,627–86,089,526, 2 genes: AC092723.2, AC135012.1.
- chr16:86,764,298–86,961,268, 3 genes (within-gene range 0–2): AC130467.1, AC093519.2, AC093519.1.
- chr17:6,322,413–6,435,199, 4 genes (within-gene range 0–1): BTF3P14, AC055872.2, AIPL1, AC055872.1.
- chr17:9,791,227–9,905,271, 6 genes: AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN.
- chr17:13,932,720–13,966,952, 2 genes: AC005304.1, AC005304.3.
- chr17:72,818,836–73,644,445, 15 genes (within-gene range 0–1): AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1.
- chr17:73,749,270–73,836,019, 3 genes (within-gene range 0–1): LINC00469, LINC02092, AC125421.2.
- chr18:45,423,764–45,529,855, 3 genes (within-gene range 0–1): SLC14A2-AS1, AC021517.1, AC021517.3.
- chr19:28,949,437–29,525,752, 13 genes (within-gene range 0–1): AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3.
- chr19:31,588,040–31,655,461, 3 genes: AC011525.1, AC011525.2, RNA5SP471.
- chr19:54,532,692–54,670,359, 12 genes (within-gene range 0–2): KIR3DX1, AC245036.2, LILRA2, AC245036.5, LILRA1, AC245036.4, LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3.
- chr20:50,247,643–50,321,342, 3 genes: PELATON, LINC01270, LINC01271.
- chr22:27,143,478–27,419,713, 8 genes: AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1.
- chr22:44,139,365–44,229,512, 4 genes: AL031595.3, PARVG, AL031595.1, AL031595.2.
- chr22:46,762,617–48,415,571, 18 genes (within-gene range 0–1): TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 976 genes in 66 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,612,006–151,771,334, 14 genes, copy number 6: SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5.
- chr1:202,851,828–202,958,572, 7 genes, copy number 5: TUBA5P, ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1.
- chr1:248,436,359–248,919,946, 31 genes, copy number 5–8: OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:130,270,440–131,410,050, 79 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:206,203,543–206,420,238, 8 genes, copy number 5 (within-gene range 3–5): GPR1-AS, RN7SKP200, ATP5POP1, HMGN1P6, RN7SKP260, ZDBF2, ACER2P1, HNRNPA1P51.
- chr3:198,071,311–198,222,513, 5 genes, copy number 11: RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr5:73,337,906–73,509,254, 9 genes, copy number 5: LINC02230, AC099522.1, FOXD1, FOXD1-AS1, LINC01385, LINC01386, AC099522.2, BTF3, FUNDC2P1.
- chr5:138,252,380–141,512,981, 161 genes, copy number 5–13 (within-gene range 3–13) (broad region; genes not listed).
- chr5:141,882,815–142,037,125, 9 genes, copy number 8: AC005740.5, AC005740.1, DELE1, PCDH12, AC005740.4, RNF14, AC005740.3, GNPDA1, AC005740.2.
- chr5:180,784,780–181,131,169, 20 genes, copy number 5 (within-gene range 4–5): MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1.
- chr6:3,023,142–3,303,373, 16 genes, copy number 5–11 (within-gene range 2–11): HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2, RIPK1, AL031963.3, RNA5SP201, BPHL, AL031963.1, TUBB2A, TUBB2BP1, LINC02525, TUBB2B, PSMG4.
- chr7:149,126,416–149,867,479, 20 genes, copy number 5 (within-gene range 2–5): ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746, ZNF767P, KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1.
- chr8:150,584–264,703, 11 genes, copy number 9: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2.
- chr8:43,140,464–43,494,762, 16 genes, copy number 5 (within-gene range 2–5): HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4.
- chr9:4,984,390–5,235,304, 16 genes, copy number 6 (within-gene range 2–6): JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4.
- chr9:83,659,968–83,956,986, 7 genes, copy number 7: UBQLN1, AL354920.1, GKAP1, AL354733.1, AL354733.2, KIF27, C9orf64.
- chr9:96,490,241–97,068,628, 13 genes, copy number 7 (within-gene range 3–7): CDC14B, PRXL2C, AL589843.1, AL589843.2, ZNF510, ZNF782, MFSD14C, PTMAP11, AL158827.1, NUTM2G, YRDCP2, CTSV, TCEA1P1.
- chr10:133,420,666–133,569,835, 8 genes, copy number 5: SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1.
- chr11:167,784–442,011, 27 genes, copy number 6 (within-gene range 4–6): BET1L, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3, SIGIRR, ANO9.
- chr11:65,866,441–66,026,479, 14 genes, copy number 5 (within-gene range 2–5): EFEMP2, CTSW, FIBP, CCDC85B, FOSL1, C11orf68, DRAP1, TSGA10IP, SART1, AP006287.1, EIF1AD, BANF1, CST6, CATSPER1.
- chr11:124,766,498–124,834,487, 5 genes, copy number 6 (within-gene range 1–6): MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4.
- chr11:129,899,706–130,210,362, 9 genes, copy number 7 (within-gene range 2–7): PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14.
- chr13:18,467,172–18,895,230, 20 genes, copy number 5: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2.
- chr13:22,040,972–26,025,851, 82 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:92,762,757–92,949,230, 7 genes, copy number 5–8 (within-gene range 2–8): AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1.
- chr15:100,861,924–100,919,391, 4 genes, copy number 5 (within-gene range 2–5): AC015712.5, ALDH1A3, AC015712.7, AC015712.2.
- chr16:30,875,222–31,711,986, 73 genes, copy number 5 (broad region; genes not listed).
- chr16:53,386,944–53,703,938, 12 genes, copy number 5: AC007342.5, AC007342.8, AC007342.9, RBL2, RNU6-1153P, AC007342.1, AC007342.6, AC007342.7, AKTIP, AC007497.2, RPGRIP1L, AC007497.1.
- chr17:39,200,283–40,721,932, 70 genes, copy number 5–6 (broad region; genes not listed).
- chr18:12,040,101–12,448,205, 27 genes, copy number 5–7: AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2.
- chr18:79,395,856–79,754,510, 13 genes, copy number 5–6 (within-gene range 2–6): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2.
- chr18:79,863,668–80,247,514, 15 genes, copy number 5: KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:12,284,337–12,675,832, 30 genes, copy number 5 (within-gene range 2–5): AC012618.2, ZNF563, ZNF442, RPS29P23, AC008758.4, AC008758.3, ZNF799, AC008758.5, ZNF443, AC008758.6, AC008758.2, ZNF709, AC008758.1, MTND2P40, MTCO1P27, MTCO2P27, MTATP6P27, PPIAP20, ZNF564, AC010422.6, AC010422.4, AC010422.1, PGK1P2, ZNF490, ZNF791, RPL10P16, AC010422.3, MAN2B1, AC010422.5, WDR83.
- chr19:22,501,699–22,533,494, 4 genes, copy number 5: AC004004.1, AC011467.6, AC011467.1, LINC01233.
- chr19:55,591,376–55,709,858, 14 genes, copy number 6 (within-gene range 1–6): FIZ1, ZNF524, ZNF865, AC008735.4, ZNF784, ZNF580, ZNF581, CCDC106, U2AF2, AC008735.2, AC008735.1, EPN1, AC010525.1, AC010525.2.
- chr20:38,446,343–38,651,035, 9 genes, copy number 5: SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1.
- chr20:45,469,753–45,547,662, 8 genes, copy number 7 (within-gene range 4–7): WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21.
- chr20:50,040,716–50,192,668, 9 genes, copy number 5: TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB.
- chr21:37,062,846–37,268,497, 9 genes, copy number 5: PIGP, TTC3, AP001429.1, TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1.
- chr22:24,540,423–24,712,520, 15 genes, copy number 5–9: GUCD1, SNRPD3, AP000356.5, LRRC75B, GGT1, AP000356.1, BCRP3, AP000356.4, AP000356.3, AP000356.2, POM121L10P, ARL5AP4, AP000357.1, AP000357.2, CRIP1P4.

Autosomal genes at a single copy (total copy number 1): 12,749. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
